CCDI case PBCIJM — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/8d7f3401-174b-4b8d-8641-1691edc37353

Demographics
Sex at birth: male; Race: native hawaiian or other pacific islander.

Diagnoses (1)
1. Astrocytoma, NOS: ICD-O-3 morphology code: 9400/3; Tissue or organ of origin: Temporal lobe; Age at diagnosis: 13.2 years (4,837 days).

Biospecimens (3 samples)
- Sample 0DSP25: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DSP27: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DSP2J: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
